Surgical pathology report (de-identified scan), TCGA case TCGA-DE-A0Y2, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of North Carolina, specimen TCGA-DE-A0Y2-01A (Primary Tumor).

[page 1 of 2]
Case Number :

1CD-0-3

Collection Date .

Carcinoma Papillary thyroid 8260/3
Site: thyroid, NOS C73.9

2/18/11 *hr*

Surgical Pathology Report

Diagnosis:

A: Thyroid, total thyroidectomy

Histologic tumor type: papillary thyroid carcinoma

Tumor size: 2.3 cm

Tumor growth pattern: papillary architecture

Extent of invasion:

Location: unilateral, left lobe

Extra-capsular: not identified

Vascular: not identified

Multicentricity: multifocal (small satellite nodule in A13)

Surgical margins: negative but close (<1 mm to anterior (A11), 1 mm to posterior (A8-A10)

Background thyroid: no significant histologic abnormality

Lymph nodes: metastatic papillary thyroid carcinoma (1/1, block A14)

AJCC stage: pT2 pN1a pMx

B: Lymph nodes, level 6, left cervical, dissection

- Metastatic papillary thyroid carcinoma (5/10), largest metastasis 5 mm diameter, without extracapsular extension.

Clinical History:

a clinical diagnosis of thyroid cancer.

Gross Description:

Received are two appropriately labeled containers.

Specimen A:

Specimen fixation: Formalin

Type of specimen: Total thyroidectomy

Size and weight of specimen: 13.6 grams, 6 x 4 x 3 cm thyroidectomy specimen. The lobes are of approximately equal size with the left lobe slightly larger.

Orientation: There is a stitch indicating the left lobe, per the specimen container. At the time of tissue procurement triage, the specimen was inked as follows: anterior/blue, posterior/black and isthmus (both anterior and posterior surfaces)/yellow.

[page 2 of 2]
Tumor location: Left mid to inferior lobe

Tumor description: Solitary relatively well circumscribed lesion with scalloped borders. The mass is not encapsulated and has a friable pink/tan cut surface which is peripherally discolored yellow. It is unclear whether the

yellow area (1.2 cm in greatest dimension) is a separate entity, but abuts the otherwise pink/tan somewhat soft lesion.

Tumor size: 2.4 x 2.2 x 1.3 cm (yellow area 1.2 x 0.9 x 0.5 cm, red softer lesion 2.2 x 1.3 x 1.2 cm).

Confinement/non-confinement to the thyroid gland: Grossly confined to the thyroid.

Distance of tumor from surgical margins: The mass is abutting the blue inked anterior margin, focally 1 mm or less to the black inked posterior margin.

Appearance of thyroid gland away from tumor: The left thyroid consists of red/brown glistening normal appearing thyroid parenchyma. Sectioning through the right thyroid lobe exhibits unremarkable normal dark red/brown thyroid parenchyma with no abnormalities identified.

Tissue submitted for special investigations: A portion of the tumor was taken by tissue procurement.

Lymph nodes: N/A

Digital photograph taken: No

Block Summary:

Inking: anterior/blue, posterior/black, isthmus/yellow

A1-A6 - Right lobe from superior to inferior, respectively

A7-A14 - Left lobe from superior to inferior, respectively, .

Container B is additionally labeled "left level 6 cervical lymph nodes" and is a 1.5 x 1.0 x 0.8 cm aggregate of multiple small focally cauterized pink/brown lymphoid fragments from 2 x 2 x 2 mm to 1.4 x 0.6 x 0.5 cm. The smallest fragments are entirely submitted in block B1. The larger fragment is serially sectioned and submitted in block B2, .

Light Microscopy:

Light microscopic examination is performed

Signature

Attending Pathologist:

I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Electronically Signed by:

Source: NCI Genomic Data Commons file 854c71f0-5371-4978-b61e-1dbba5379d5d (TCGA-DE-A0Y2.E564FC79-47F7-4CE8-873D-3A8B697C7FF8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).